Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4810, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4810-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: BONE, LEFT 11TH RIB, EXCISION –
PORTION OF RIB BONE WITH NORMOCELLULAR MARROW SHOWING TRILINEAGE HEMATOPOIESIS;
NEGATIVE FOR TUMOR.

PART 2: LEFT KIDNEY, RADICAL NEPHRECTOMY –

- A. INVASIVE MODERATELY TO POORLY DIFFERENTIATED RENAL CELL CARCINOMA, MIXED CLEAR CELL AND GRANULAR CELL TYPES (FUHRMAN GRADE 3/4), 11.5 CM.
- B. INVASIVE TUMOR EXTENDS TO PERIRENAL ADIPOSE TISSUE, RENAL PELVIC ADIPOSE TISSUE, AND INVADDES THE PROXIMAL RENAL VEIN; BUT DOES NOT EXTEND BEYOND GEROTA'S FASCIA.
- C. VASCULAR AND URETERAL MARGINS ARE NEGATIVE FOR TUMOR.
- D. THE TWO OF TWO HILAR LYMPH NODES WITH METASTATIC RENAL CELL CARCINOMA.
- E. LEFT ADRENAL GLAND, NEGATIVE FOR TUMOR.
- F. PATHOLOGIC STAGE T3; N1; MX; G3.
- G. SURROUNDING KIDNEY PARENCHYMA WITH MASSIVE FAT.

PART 3: LYMPH NODE, RETROPERITONEUM, EXCISION –
FOUR BENIGN REACTIVE LYMPH NODES, NO TUMOR SEEN.

PART 4: LYMPH NODE, PERIHILAR, EXCISION –
PERIPHERAL NERVE AND GANGLIA; NO LYMPHOID TISSUE OR TUMOR SEEN.

Final Diagnosis

URINE:

SATISFACTORY FOR INTERPRETATION.

ATYPICAL UROTHELIAL CELLS IN CLUSTERS AND SINGLE CELLS, SUSPICIOUS FOR MALIGNANCY
RULE OUT UROTHELIAL CARCINOMA

Final Diagnosis

BONE, FIBULA, RIGHT, BIOPSY –

ATYPICAL CELLS WITH CLEAR CELL AND GRANULAR CELL MORPHOLOGY, CONSISTENT WITH METASTATIC RENAL CELL CARCINOMA.

Comment:

Slides from previous kidney neoplasm. The morphology of the current bone lesion is similar to previous renal lesion. Immunohistochemistry will be performed to confirm the diagnosis. Results will be issued in an addendum.

Addendum

Addendum

The immunohistochemical examination was performed by using antibodies against cytokeratin 7 (CK7), cytokeratin 20 (CK20), CD10, vimentin and epithelial membrane antigen (EMA). The neoplastic cells stained with EMA, vimentin and CD10, but not with CK7 or CK20. These findings strongly support the diagnosis of metastatic renal cell carcinoma. Clinical correlation is recommended.

Final Diagnosis

Urine:

SATISFACTORY FOR INTERPRETATION.

NEGATIVE. NO MALIGNANT CELLS SEEN.

Smears show granular casts with few wbc's and rare rbc's.

Final Diagnosis

Urine:

SATISFACTORY FOR INTERPRETATION.

NEGATIVE. NO MALIGNANT CELLS SEEN.

RBCS NOTED.

Source: NCI Genomic Data Commons file 17f59a52-c33d-448b-93c6-4ebec5b3efb4 (TCGA-B0-4810.8F4D743F-D115-484D-B01D-0CEEA8EBC2AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).